Somatic mutation profile of tumor specimen TCGA-AA-3520-01A (aliquot TCGA-AA-3520-01A-01D-1953-10) from TCGA case TCGA-AA-3520, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage II; Age at diagnosis: 86.3 years (31,531 days).
Specimen TCGA-AA-3520-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7d6b2995-0510-4144-bb93-c2bbaa1a5aeb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3520-11A (Solid Tissue Normal), aliquot TCGA-AA-3520-11A-01D-1554-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4aa26857-4a55-4434-9bd6-029e82705e15

The open-access MAF lists 28 somatic variants for this specimen: 18 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 15, Silent 10, Splice Site 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP10A | c.2074C>T p.R692W | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.892); catalogued as rs1288765192, COSV100791095; called by muse, mutect2, varscan2
- CCDC73 | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs559461829, COSV100067140; called by muse, mutect2, varscan2
- CFAP46 | c.755+1G>A p.X252_splice | Splice Site (SNP) | VAF 39/171 reads (23%) | catalogued as rs1358664271, COSV100886436; called by muse, mutect2, varscan2
- COL18A1 | c.3200C>T p.A1067V (on ENST00000359759 / NM_130444.3; = p.A832V on NM_030582.4) | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as rs1436717929, COSV100645167; called by muse, mutect2, varscan2
- CUX2 | c.639G>A p.A213= | Splice Region (SNP) | VAF 62/218 reads (28%) | catalogued as rs375250431; called by muse, mutect2, varscan2
- DIAPH1 | c.265G>T p.D89Y | Missense Mutation (SNP) | VAF 61/163 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99526344; called by muse, mutect2, varscan2
- FCAMR | c.108C>A p.H36Q | Missense Mutation (SNP) | VAF 148/463 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs776183391, COSV100249388; called by muse, mutect2, varscan2
- FCAMR | c.107A>G p.H36R | Missense Mutation (SNP) | VAF 151/471 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.04); catalogued as COSV100249391; called by muse, mutect2, varscan2
- FRYL | c.3005G>A p.G1002D | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as COSV99976616; called by muse, mutect2, varscan2
- GCK | c.700T>C p.Y234H | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as CM096864, COSV100357151; called by muse, mutect2, varscan2
- JAKMIP1 | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99289262, COSV99291030; called by muse, mutect2, varscan2
- NDOR1 | c.1186C>T p.R396W | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs1348672232, COSV100788942; called by muse, mutect2, varscan2
- NOS1 | c.3776C>G p.A1259G | Missense Mutation (SNP) | VAF 117/301 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100500384, COSV57606021; called by muse, mutect2, varscan2
- PACS2 | c.2551+2T>C p.X851_splice | Splice Site (SNP) | VAF 45/77 reads (58%) | catalogued as COSV100330686; called by muse, mutect2, varscan2
- PRDM15 | c.182G>A p.R61Q | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.014); catalogued as rs779785673, COSV99519884; called by muse, mutect2, varscan2
- RFX1 | c.350C>T p.S117L | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as rs753088781, COSV54332692; called by muse, mutect2, varscan2
- TSSK1B | c.969G>T p.Q323H | Missense Mutation (SNP) | VAF 81/230 reads (35%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.101); catalogued as COSV101181037; called by muse, mutect2, varscan2
- ZNF423 | c.2282C>T p.T761M (on ENST00000563137 / NM_001379286.1; = p.T753M on NM_015069.4) | Missense Mutation (SNP) | VAF 49/130 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1462999528, COSV52196556; called by muse, mutect2, varscan2
- ADAMTS2 | c.2865C>T p.H955= | Silent (SNP) | VAF 19/30 reads (63%) | catalogued as rs752790963, COSV52364952; ClinVar: likely benign; called by muse, mutect2, varscan2
- KCNC1 | c.342C>T p.D114= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs1387145999, COSV99789092; called by muse, mutect2
- NR2F6 | c.1074C>T p.P358= | Silent (SNP) | VAF 40/99 reads (40%) | catalogued as rs371438824; called by muse, mutect2, varscan2
- PCDHA6 | c.276C>T p.R92= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as rs782811756, COSV100972221; called by muse, mutect2, varscan2
- RXFP3 | c.171G>A p.P57= | Silent (SNP) | VAF 37/108 reads (34%) | catalogued as rs769554354, COSV57507450; called by muse, mutect2, varscan2
- SCAF11 | c.448T>C p.L150= | Silent (SNP) | VAF 101/297 reads (34%) | catalogued as COSV99874000; called by muse, varscan2
- SCRT2 | c.867G>C p.A289= | Silent (SNP) | VAF 13/25 reads (52%) | catalogued as COSV99857055; called by muse, varscan2
- SEMA3G | c.2052T>C p.P684= | Silent (SNP) | VAF 50/182 reads (27%) | catalogued as COSV99202291; called by muse, mutect2, varscan2
- SPEG | c.456C>T p.D152= | Silent (SNP) | VAF 45/126 reads (36%) | catalogued as rs201002745, COSV56668028; called by muse, mutect2, varscan2
- ZSCAN20 | c.1188A>G p.P396= | Silent (SNP) | VAF 22/94 reads (23%) | catalogued as COSV100792553; called by muse, mutect2, varscan2
